Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8687, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8687-01A (Primary Tumor).

[page 1 of 3]
[Redacted]

[Redacted] Case ID	Gross Description	Microscopic Description	Diagnosis Details
[Redacted]			

[page 2 of 3]
Comments	Formatted Path Report
	STOMACH TISSUE CHECKLIST Specimen type: Gastrectomy Tumor site: Cardia Tumor size: 6 x 6 x 1.2 cm Tumor features: None specified Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Adjacent structures (specify) - Esophagus, lesser omentum Lymph nodes: 5/9 positive for metastasis (Intraabdominal 5/9) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

ica ID

[page 3 of 3]
Excision date

████████████████████

Source: NCI Genomic Data Commons file 2acd36ee-ff66-4763-9a83-a4212a97e1e0 (TCGA-BR-8687.31932076-B23B-4BD9-A544-DED399AE5723.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).